Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A6M6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A6M6-01A (Primary Tumor).

[page 1 of 4]
Surg Path Final Report
Temporary Copy

Page 1 of 3

Case:

Collected:

Ordered by:

Patient:

ID:

Location:

ACCESSION

Submitting Physician

General Surgery

Clinical History

Not provided

Diagnosis

1. "GALLBLADDER", (CHOLECYSTECTOMY):

- GALLBLADDER WITH ROKITANSKY-ASCHOFF SINUSES.
- NO EVIDENCE OF SIGNIFICANT INFLAMMATION.
- NO EVIDENCE OF NEOPLASTIC CHANGE.

2. "CENTRAL HEPATECTOMY SECTIONS 4, 5, 8", (PARTIAL HEPATECTOMY):

- POORLY DIFFERENTIATED CARCINOMA MOST CONSISTENT WITH HEPATOCELLULAR CARCINOMA.
- CARCINOMA MEASURES 11.5 X 6.8 X 6.0 CM.
- CARCINOMA SHOWS EXTENSIVE LYMPHOVASCULAR INVASION.
- CARCINOMA IN NONREACTIVE WITH ANTIBODIES DIRECTED AGAINST CK7, CK20, AND HSA.
- CARCINOMA EXTENDS FOCALLY TO HEPATIC RESECTION LINE (BLACK INK SLIDE 2E).
- CARCINOMA IS MULTINODULAR WITH NODULES EXTENDING BEYOND MAIN TUMOR MASS.
- CARCINOMA ARISES IN BACKGROUND OF CIRRHOSIS WITH MILD TO MODERATE STEATOSIS.
- SCATTERED BILE DUCT HAMARTOMAS PRESENT.
- PLEASE SEE SYNOPTIC REPORT.

ICD-O-3
Carcinoma, hepatocellular ^{NDS}
8170/3

Site Liver C22.0

JA 7/24/13

I certify that I personally conducted the diagnostic evaluation on the above specimens and have rendered the above diagnosis(es):

electronic signature

Department of Pathology

For questions regarding this case, call

Gross Description

Received are two specimens, in formalin, each labeled with the patient's name and specimen identification.

Specimen one is labeled "gallbladder", and consists of an intact, 6.8 x 3.5 x 3.0 cm bile-stained gallbladder. The serosa is smooth and unremarkable; hepatic surface is unremarkable. The specimen is opened and releases approximately 15 cc of green viscus bile and reveals a black-green bile stained mucosal surface, which is overall velvety and unremarkable. The specimen is absent of gallstones. Representative tissue to include neck margin is submitted in cassette 1A. The

[page 2 of 4]
Surg Path Final Report

Temporary Copy

Page 2 of 3

Case: [REDACTED]

Collected: [REDACTED]

Ordered by: [REDACTED]

Patient: [REDACTED]

ID: [REDACTED]

Location: [REDACTED]

remaining specimen is returned to formalin.

Specimen two is labeled "central hepatectomy section 4, 5, 8", and consists of a 450.0 g, 17.0 x 9.5 x 7.0 cm segment of unoriented liver. The hepatic capsule of the anterior surface is intact and the central surface has a bulging, multinodular tumor mass, 11.0 x 7.5 and protruding 1.3 cm above the uninvolved anterior surface, the opposing surface consisting of surgical resection margin is peppered with surgical staples and multiple linear surgical resection lines extending from 3.5-6.5 cm in length. Vasculature is amputated flush to the hepatic margin. The specimen is inked, is serially sectioned, and has an ill-demarcated, irregular, 11.5 x 6.8 x 6.0 cm tumor mass approaching to within 0.1 cm of the hepatic capsule margin and 0.4 cm from the hepatic resection margin. The tumor has a multinodular, yellow-white to pink-tan, bulging, solid cut surface with scattered peripheral nodules. Ink code is as follows: Anterior capsule margin - yellow; surgically stapled resection line - blue; hepatic resection line - black. Representative tissue is submitted as follows: 2A-2G - tumor approaching nearest surgical resection margins and hepatic capsule margin; 2H-2I - tumor. The remaining specimen is returned to formalin.

Microscopic Examination

Performed.

Synoptic Report

Based on AJCC/UICC TNM, 7th edition
Protocol web posting date:

Hepatocellular carcinoma: Hepatic resection

Specimen:

Liver segments 4, 5 and 8

Procedure:

Partial Hepatectomy

Major hepatectomy (three segments)

Tumor size:

Greatest dimension: 11.5 cm

*Additional dimensions: 6.8 x 6.0 cm

Tumor focality:

Multiple foci in segments 4, 5 and 8

Histologic type:

Other: Poorly differentiated carcinoma favor hepatocellular carcinoma

Histologic grade:

G3: Poorly differentiated

Tumor extension:

Confined to liver

Margins:

Parenchymal margin: Involved by invasive carcinoma (section 2E)

Lymphovascular invasion:

Present

Microscopic small vessel invasion:

Indeterminate

*Perineural invasion:

indeterminate

Pathologic staging (pTNM):

Primary tumor (pT): pT2

Regional lymph nodes (pN): pNX: Cannot be assessed

Distant metastasis (pM): Not applicable

*Ancillary studies:

[page 3 of 4]
Surg Path Final Report
Temporary Copy

Page 3 of 3

Case:

Collected:

Ordered by:

Patient

ID:

Location:

Specify: Immunohistochemistry for CK7, CK20, and HSA nonreactive in sections studied.

Site-A Discrepancy		☒
Diagnosis Discrepancy Primary Site		☒

[page 4 of 4]
Addendum Report
Temporary Copy

Page 1 of 1

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Patient: [REDACTED]
ID: [REDACTED]
Location: [REDACTED]

ACCESSION

Addendum Discussion

At the request of [REDACTED] the material was re-reviewed for margin status. Carcinoma cells are present at the black-inked operative margin. This operative margin is designated as hepatic resection line in the gross description. Thus malignant cells are present at the hepatic resection line.

[REDACTED] I certify that I personally conducted the diagnostic evaluation on the above specimen(s) and have rendered the above diagnosis(es):

[REDACTED]
electronic signature

Source: NCI Genomic Data Commons file eb014856-903b-4cd3-9928-ae8d17113f55 (TCGA-RC-A6M6.210AAA2E-0B18-4C08-815D-BC523FF2A7D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).